Somatic mutation profile of tumor specimen TCGA-DK-AA6T-01A (aliquot TCGA-DK-AA6T-01A-11D-A391-08) from TCGA case TCGA-DK-AA6T, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 63.5 years (23,198 days).
Specimen TCGA-DK-AA6T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a66f9b0-4e4f-41ba-8ced-88edfed1766c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6T-10A (Blood Derived Normal), aliquot TCGA-DK-AA6T-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8f01746-5b9e-483c-af79-6194827f9a0c

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Nonsense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as rs587778842, CM951104, COSV57299867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.778C>G p.H260D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV101518387; called by muse, mutect2, varscan2
- AFF2 | c.257C>G p.T86S | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100648757, COSV60682037; called by muse, mutect2, varscan2
- ALKBH5 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV101213226; called by muse, mutect2, varscan2
- BBS9 | c.2020C>T p.R674W (on ENST00000242067 / NM_001348036.1; = p.R634W on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368526968; called by muse, mutect2, varscan2
- BOD1L1 | c.5527T>A p.L1843I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99238179; called by muse, mutect2, varscan2
- C4BPB | c.528G>C p.E176D | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99699828; called by muse, mutect2, varscan2
- C7 | c.1939C>G p.P647A | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100495273; called by muse, mutect2, varscan2
- CACNA1B | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV53135708; called by muse, mutect2, varscan2
- CCDC125 | c.1071G>A p.W357* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs561994282, COSV101143427; called by muse, mutect2, varscan2
- CFAP54 | c.5290G>C p.V1764L | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV100732877; called by muse, mutect2, varscan2
- CNST | c.1865T>C p.I622T | Missense Mutation (SNP) | VAF 102/188 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100830162; called by muse, mutect2, varscan2
- COL6A3 | c.4531G>A p.G1511R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99795983; called by muse, mutect2
- DAGLB | c.936A>C p.R312S | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as COSV99765627; called by muse, varscan2
- DNMBP | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770100956, COSV60621881; called by muse, mutect2, varscan2
- EPRS1 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV65101935; called by muse, mutect2, varscan2
- FERMT3 | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99656234; called by muse, mutect2, varscan2
- GMIP | c.1944G>C p.K648N | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99179063; called by muse, mutect2, varscan2
- GRIN3A | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100701326; called by muse, mutect2, varscan2
- IGLV5-45 | c.211T>G p.Y71D | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs772961929; called by muse, varscan2
- INPP5E | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.744); catalogued as COSV100867194; called by muse, mutect2, varscan2
- IRF3 | c.1232A>C p.Y411S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as COSV100566776; called by muse, mutect2, varscan2
- KIF26A | c.3677C>G p.A1226G | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100180646; called by muse, mutect2, varscan2
- LMNB2 | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100321885; called by muse, mutect2, varscan2
- LRRC4C | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99536734; called by muse, mutect2, varscan2
- NAT16 | c.807C>G p.D269E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV100296166; called by muse, mutect2
- NOL6 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1417845437, COSV99954357; called by muse, mutect2, varscan2
- NOS1 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412760885, COSV57606502; called by muse, mutect2, varscan2
- PATJ | c.570C>G p.H190Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.211); catalogued as COSV100332942; called by muse, mutect2, varscan2
- PCLO | c.3961C>G p.P1321A | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100426650, COSV61637268; called by muse, mutect2, varscan2
- PIK3CD | c.376C>G p.H126D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63132789; called by muse, mutect2, varscan2
- POLE | c.1611G>C p.E537D | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57693609; called by muse, mutect2, varscan2
- PPP1R3D | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as rs1372663034, COSV100674351; called by muse, mutect2, varscan2
- RBM17 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs371677234; called by muse, mutect2, varscan2
- REEP4 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100098007; called by muse, mutect2, varscan2
- SEC23A | c.1295G>A p.C432Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs776413541, COSV100304993; called by muse, mutect2, varscan2
- SEMA3D | c.1294T>G p.Y432D | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV99405664; called by muse, mutect2, varscan2
- SEMA3E | c.2159G>C p.S720T | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs372156795; called by muse, mutect2, varscan2
- SHANK2 | c.2995G>C p.A999P | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV99571847; called by muse, mutect2, varscan2
- SLC2A8 | c.842C>G p.T281S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.099); catalogued as COSV100972585; called by muse, mutect2, varscan2
- SLC6A15 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 99/165 reads (60%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.428); catalogued as rs768286786, COSV57024300, COSV99880036; called by muse, mutect2, varscan2
- SLFN11 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV100390291; called by muse, mutect2, varscan2
- STAT2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs897268737, COSV58474945; called by muse, mutect2, varscan2
- SYK | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | catalogued as COSV65331380; called by muse, mutect2, varscan2
- TMEM273 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100939569; called by muse, mutect2
- TRIM56 | c.1826G>C p.G609A | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.19); catalogued as COSV100046845; called by muse, mutect2, varscan2
- ZC2HC1C | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264542848, COSV53172391; called by muse, mutect2
- ZFP36L1 | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 80/165 reads (48%) | catalogued as COSV100322398; called by muse, mutect2, varscan2
- ZNF566 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.353); catalogued as COSV101091201; called by muse, mutect2, varscan2
- ZNF70 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100558808; called by muse, mutect2, varscan2
- IGKV5-2 | c.121A>C p.I41L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); called by muse, varscan2
- IGLC3 | c.190A>G p.N64D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IGLV4-3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGLV7-43 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- APOBEC3F | c.273A>C p.V91= | Silent (SNP) | VAF 61/110 reads (55%) | catalogued as COSV100415088; called by muse, mutect2, varscan2
- CYP2D6 | c.555G>C p.V185= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100637227; called by muse, mutect2, varscan2
- DMRTB1 | c.657G>A p.P219= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs1183292973, COSV65114152; called by muse, mutect2, varscan2
- FBN2 | c.1104G>A p.S368= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs138063920, COSV99324372; called by muse, mutect2, varscan2
- IGHV2-70 | c.306A>G p.T102= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs377122389; called by muse, mutect2, varscan2
- IGKV5-2 | c.186A>G p.E62= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs562736227; called by muse, varscan2
- IGLV7-43 | c.141A>G p.A47= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs369087560; called by muse, mutect2, varscan2
- KIF13A | c.1188C>T p.L396= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs780169410, COSV99432957; called by muse, mutect2
- KIRREL3 | c.249C>T p.D83= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs372305474; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP10 | c.313C>T p.L105= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100612247; called by muse, mutect2, varscan2
- LRRC56 | c.1398G>A p.P466= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs746149171, COSV99529341; called by muse, mutect2, varscan2
- LRRN4 | c.2094C>T p.T698= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs559212508, COSV101125344; called by muse, mutect2, varscan2
- PXDNL | c.3288G>T p.G1096= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100680707; called by muse, mutect2, varscan2
- SURF6 | c.840G>C p.V280= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs1228252948, COSV100921112; called by muse, mutect2, varscan2
- TM4SF5 | c.534G>C p.V178= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99564521; called by muse, mutect2, varscan2
- USP28 | c.2031C>G p.L677= | Silent (SNP) | VAF 160/335 reads (48%) | catalogued as COSV99134413; called by muse, mutect2, varscan2
- SSPOP | n.15704G>A | RNA (SNP) | VAF 26/50 reads (52%) | catalogued as rs373429712; called by muse, mutect2, varscan2
